Surgical pathology report (de-identified scan), TCGA case TCGA-26-6173, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-6173-01A (Primary Tumor).

[page 1 of 2]
TCGA-26-6173

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Brain tumor () A. Frozen Section Charge ()
A. Glial Fibrill. Acid Prt () A. Reticulin-Gordon&Sweet ()

CLINICAL HISTORY: male with left temporal lobe lesion, 4.0 x 4.0 x 3.0 cm, consistent with glioblastoma. Presents today for tumor resection.

GROSS DESCRIPTION: Received the following specimen in the Department of Pathology, labeled with the patient's name and hospital #:

A. Brain tumor

A. The specimen is received fresh for frozen section labeled "brain tumor" and consists of a 3.9 x 3.3 x 2.0 cm, pink-tan to tan-white mass. A 1.5 x 0.7 x 0.3 cm portion of this mass has been submitted for frozen section. Frozen section diagnosis is "FSA1--diagnosis: malignant glioma, suspect glioblastoma," per . The residual frozen section tissue is submitted in cassette FSA1. The remaining mass is serially sectioned to reveal a tan-white to yellow-tan cut surface. There are diffuse areas of apparent necrosis present. Representative sections are submitted in cassettes A2-A4.

DIAGNOSIS:

A. "Brain tumor":

Glioblastoma multiforme (WHO Grade IV astrocytoma) (see comment)

COMMENT: This glioma shows prominent nuclear and cellular pleomorphism, mitotic activity, abundant vascular endothelial proliferation and pseudopalisading necrosis. Most (but not all) tumor cells are immunoreactive for GFAP and reticulin staining is primarily associated with vessels. These results support the diagnosis.

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist:

ICD9 Codes: 191.9

[page 2 of 2]
[REDACTED]

[REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Pathologist
Electronically signed [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 5c4520c2-45bc-4b59-8c32-a5ac8ff01e41 (TCGA-26-6173.436138E9-3119-4B20-BBB5-E494C68E48CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).